Gene-level copy-number profile of tumor specimen TCGA-XE-AANJ-01A from TCGA case TCGA-XE-AANJ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 39.2 years (14,314 days).
Specimen TCGA-XE-AANJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.653bb923-9228-4fac-b24a-ed4615eac9a4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XE-AANJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb7556fd-0c69-4d54-bbff-ac220cca16d7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,100; copy number 2: 23,711; copy number 3: 25,163; copy number 4: 7,870; copy number 5: 522; copy number 6: 47; copy number 7: 11; copy number 8: 173; copy number 9: 660; copy number 10: 76; copy number 11: 318; copy number 12: 28; copy number 15: 21; copy number 16: 58; copy number 22: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XE-AANJ-01A-11D-A434-01): tumor purity 0.59, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,400 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,670,878–198,222,513, 636 genes, copy number 9–10 (broad region; genes not listed).
- chr12:66,767–5,046,788, 129 genes, copy number 8–11 (broad region; genes not listed).
- chr12:5,388,589–12,917,937, 341 genes, copy number 8–11 (broad region; genes not listed).
- chr12:14,365,632–28,581,511, 228 genes, copy number 7–22 (within-gene range 6–22) (broad region; genes not listed).
- chr12:30,454,919–32,646,050, 66 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,100. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
